Surgical pathology report (de-identified scan), TCGA case TCGA-PN-A8MA, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Institute of Human Virology Nigeria, specimen TCGA-PN-A8MA-01A (Primary Tumor).

[page 1 of 2]
Age:

Sex: Female

Tissue Source Site (TSS):

Date of Tumour Procurement:

ICD O-3
Carcinoma, squamous cell, large
cell, non-keratinizing 8072/3
Site: Cervix NOS C53.9
J 5 4/4/14

1. **GROSS ASSESSMENT:** Cut section showed a chalky white tumour.

2x1.3x1cm.

2. MICROSCOPIC ASSESSMENT

Microscopic description: Section shows an invasive tumour growing in solid nests. It is composed of large polygonal cells having moderately pleomorphic hyperchromatic nuclei and amphophilic cytoplasm. The stroma is desmoplastic containing thin-walled vascular channels and similar tumour cells.

3. **Tumour Type:** Malignant

4. **Tumour Site:** Cervix

5. **Distance of invasive carcinoma to closest margin:** 3mm

- Which margin? Deep resection

[page 2 of 2]
TSS Unique patient ID:

6. **HISTOLOGICAL DIAGNOSIS:** Squamous cell carcinoma, Large cell Non
Keratinizing

7. **COMMENTS:** Nuclear score 3

Reporting Pathologist Name

Signature

Date

Diagnosis Consistent		/
HPV A Discrepancy		/
ECG Discrepancy History		/
Use of Synchronous Primary Noden		/

Source: NCI Genomic Data Commons file 87824657-a246-44b9-8f00-569d12946d54 (TCGA-PN-A8MA.A124C1F0-5522-4A98-8A3D-6A8E6A919102.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).